Somatic mutation profile of tumor specimen TCGA-08-0386-01A (aliquot TCGA-08-0386-01A-01D-1492-08) from TCGA case TCGA-08-0386, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.1 years (27,053 days).
Specimen TCGA-08-0386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d96351e-1c5c-45a5-b89e-7e4a24d9f4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-08-0386-11A (Solid Tissue Normal), aliquot TCGA-08-0386-11A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/687c664e-9f6c-42e3-98c3-12d9010675bd

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL21A1 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV55166932; called by muse, mutect2
- DDAH1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as rs756689761, COSV52303391; called by muse, mutect2, varscan2
- MTMR12 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.683); catalogued as rs780269116, COSV53785239; called by muse, mutect2, varscan2
- MX1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs749753042, COSV55818625; called by muse, mutect2
- MYH1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1291893077, COSV56849076, COSV56850582; called by muse, mutect2, varscan2
- MZF1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV53041916; called by muse, mutect2, varscan2
- PKN2 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV65143304; called by muse, mutect2
- PLCD1 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.136); catalogued as COSV52185365, COSV99379107; called by muse, mutect2
- RIPK3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.791); catalogued as rs1416987664, COSV53475952; called by muse, mutect2
- SLC9C1 | c.1447T>C p.L483= | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- CMPK1 | c.417C>T p.T139= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs1387263199, COSV64101861; called by muse, mutect2
- CRY2 | c.1449G>A p.V483= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV69888710; called by muse, mutect2, varscan2
- OR14C36 | c.786G>A p.A262= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as rs143199703, COSV58601678; called by muse, mutect2, varscan2
- PHF1 | c.19C>T p.L7= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV65702901; called by muse, mutect2
- SPHK2 | c.1851C>T p.G617= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs774380668, COSV55338376; called by muse, mutect2, varscan2
